Gene-level copy-number profile of tumor specimen TCGA-CV-A6JN-01A from TCGA case TCGA-CV-A6JN, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; Tumor grade: G1; Age at diagnosis: 53.8 years (19,635 days).
Specimen TCGA-CV-A6JN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.cde27ac4-52b1-4aa8-b689-1200c42f875d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-A6JN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8f92b4eb-207b-499a-9fd8-ade2a3cb0b76

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 10,064; copy number 2: 46,089; copy number 3: 1,890; copy number 4: 1,534; copy number 5: 89; copy number 7: 99; copy number 9: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-A6JN-01A-11D-A31K-01): tumor purity 0.56, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:245,614,773–245,676,478, 2 genes: AC104462.2, AC104462.1.
- chr3:59,747,277–61,251,459, 1 gene (within-gene range 0–1): FHIT.
- chr3:60,616,822–60,856,605, 6 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr5:59,703,606–59,703,703, 1 gene: MIR582.
- chr10:87,945,502–88,049,823, 3 genes: RPL11P3, AC063965.1, MED6P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 217 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:65,823,022–70,436,584, 211 genes, copy number 5–9 (within-gene range 2–9) (broad region; genes not listed).
- chr11:70,477,277–70,706,068, 6 genes, copy number 7–9: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.

Autosomal genes at a single copy (total copy number 1): 7,688. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
